Somatic mutation profile of tumor specimen BA2103D (aliquot aq-BA2103D) from BEATAML1.0 case 2514, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.9 years (20,034 days).
Specimen BA2103D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44436bea-454a-4fa0-8915-07e6d9b4a17b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2408D (Solid Tissue Normal), aliquot aq-BA2408D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c7e8a405-3e79-402d-962b-a663505d1895

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Frame Shift Ins 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2508_2510del p.I836del | In Frame Del (DEL) | VAF 22/136 reads (16%) | catalogued as rs121913490; ClinVar: likely pathogenic; called by pindel, varscan2
- SRSF2 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 55/90 reads (61%) | hotspot (GDC flag); SIFT tolerated (0.57); PolyPhen benign (0.398); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by muse, mutect2, varscan2
- FLT3 | c.2522A>T p.N841I | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV54046159, COSV54056042; called by muse, varscan2
- HBE1 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs951116404, COSV53080301; called by muse, mutect2
- LRP4 | c.1058C>T p.T353M | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.374); catalogued as rs769661653; called by muse, mutect2, varscan2
- MYO19 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.612); catalogued as rs757152997; called by muse, mutect2
- NPM1 | c.863_864insCCTG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 19/58 reads (33%) | catalogued as rs1554138189, COSV51543231, COSV51545499, COSV51554041, COSV51557774, COSV51563665; called by pindel, varscan2
- SEMA5A | c.1903G>A p.V635M | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66795171; called by muse, varscan2
- SOX5 | c.1001G>A p.G334D | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.307); catalogued as COSV100508079; called by muse, mutect2, varscan2
- ZNF790 | c.905G>T p.R302I | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV63211932; called by muse, mutect2
- DNAH2 | c.3457G>A p.A1153T | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, varscan2
- DOCK3 | c.6029C>A p.P2010H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- HRNR | c.3365C>A p.S1122Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- CYP21A2 | c.274A>C p.R92= | Silent (SNP) | VAF 73/174 reads (42%) | catalogued as CM161360; called by muse, mutect2, varscan2
- KIF21B | c.4530C>T p.L1510= (on ENST00000422435 / NM_001252100.2; = p.L1497= on NM_017596.4) | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as rs150393728; called by muse, mutect2, varscan2
- LILRB3 | c.1314T>G p.G438= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as rs770310553; called by muse, mutect2
- PCDH7 | c.2997T>C p.S999= | Silent (SNP) | VAF 36/67 reads (54%) | called by muse, mutect2, varscan2
- CT55 | c.-2C>T | 5'UTR (SNP) | VAF 37/85 reads (44%) | catalogued as rs782419674, COSV99358924; called by muse, mutect2, varscan2
